Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5108, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5108-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, LEFT, NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, CLEAR CELL TYPE, CONVENTIONAL (CLEAR CELL TYPE) WITH CYSTIC AND MYXOID CHANGES.
- B. FUHRMAN NUCLEAR GRADE IS 2 OF 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 5.5 CM.
- D. THE CARCINOMA EXTENDS TO THE RENAL SINUS FAT (SLIDES E AND F).
- E. THE NEOPLASM IS CONFINED TO THE RENAL CAPSULE.
- F. NO RENAL VEIN INVASION IS IDENTIFIED.
- G. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- H. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- I. THE NON-NEOPLASTIC KIDNEY SHOWS CHRONIC INTERSTITIAL INFLAMMATION.
- J. TNM STAGE: pT3a NX MX.

Source: NCI Genomic Data Commons file 8748f756-f3c0-4e01-ba0c-6d5ec95a24dd (TCGA-B0-5108.58244C05-D7B9-4413-BC6D-D9F71F16E65D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).